Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64W, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64W-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Brain, right frontotemporal/insular mass, and frontotemporal excision and CUSA: Anaplastic oligoastrocytoma (WHO grade III).

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to p53, IDH1-R132H and Ki-67. IDH1-R132H stain is positive consistent with IDH1 mutation. p53 protein is positive in rare cells. Ki-67 labeling is focally high. The findings support the above diagnosis.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the . For interpretation, see

Interpreted by:

Report electronically signed by

Transcribed by:

Preliminary Frozen Section Consultation:

A. Brain, right frontotemporal/insular mass, smears: Positive for neoplasm. Favor low-grade infiltrating glioma. Hold over to evaluate on permanent sections.

ALL EMBEDDED

continued next page Page 1 of 2

ICD-O-3

Oligoastrocytoma,
anaplastic 9382/3

Site R Brain, overlapping
lesion C71.8

Brain, supratentorial
C71.0

W 5/10/13

[page 2 of 2]
Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "right frontotemporal/insular mass" is a 2.8 x 2.6 x 1.1 cm portion of brain. Smears prepared. All submitted. Grossed by .

B. Received fresh labeled "right frontotemporal mass" is a 4.1 x 3.4 x 1.8 cm aggregate of brain (8 pieces). All submitted for permanent sections only. Grossed by

C. Received fresh within a trap labeled "remnants brain" is a 1.7 x 0.6 x 0.2 cm aggregate of grey-white tissue. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Right frontotemporal insular mass

- 1 Rt frontotemporal insular
- 2 Rt frontotemporal insular
- 3 Rt frontotemporal insular
- 4 Rt frontotemporal insular
- 5 Rt frontotemporal insular

Part B: Right frontotemporal mass

- 1 Rt frontotemporal mass 1
- 2 Rt frontotemporal mass 2
- 3 Rt frontotemporal mass 3
- 4 Rt frontotemporal mass 4
- 5 Rt frontotemporal mass 5
- 6 Rt frontotemporal mass 6
- 7 Rt frontotemporal mass 7
- 8 Rt frontotemporal mass 8

Part C: remnants brain

- 1 remnants

ALL EMBEDDED

END OF REPORT

Page 2 of 2

HIFAA Discrepancy		☒

lw 4/2/13

Source: NCI Genomic Data Commons file 9d828bac-dc7c-495c-8070-92410dc4f5b3 (TCGA-DB-A64W.9F52D767-A4C4-4D70-BB04-0BED173FA2D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).